Somatic mutation profile of tumor specimen 0DL0JY from CCDI case PBBYWI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 16.6 years (6,056 days).
Specimen 0DL0JY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd8c0bd7-a062-46b5-bcfa-eaa1226db4aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL0IX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53eba8ff-073f-4e19-ab11-58dbc33b422e

The open-access MAF lists 492 somatic variants for this specimen: 278 protein-altering or splice-affecting, 91 silent, 123 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 232, Silent 91, Intron 73, 5'UTR 22, 3'UTR 19, Splice Region 13, Splice Site 11, Nonsense Mutation 10, Frame Shift Del 5, 5'Flank 5, Translation Start Site 3, RNA 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC35A2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/147 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.107); catalogued as rs587776962, CM132546; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 173/182 reads (95%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.1656G>T p.W552C | Missense Mutation (SNP) | VAF 162/172 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as rs1374828821, COSV53318371; called by muse, mutect2, varscan2
- ARHGAP10 | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 237/250 reads (95%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as rs753614347; called by muse, mutect2, varscan2
- ARHGAP24 | c.1468G>A p.D490N (on ENST00000395184 / NM_001025616.3; = p.D397N on NM_031305.3) | Missense Mutation (SNP) | VAF 249/265 reads (94%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.734); catalogued as rs780813806; called by muse, mutect2, varscan2
- ARHGAP45 | c.1831G>A p.G611R | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as rs1294788367, COSV100491242; called by muse, mutect2
- BIRC6 | c.968A>G p.D323G | Missense Mutation (SNP) | VAF 100/243 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780739900; called by muse, mutect2, varscan2
- BMPR1A | c.620A>G p.K207R | Missense Mutation (SNP) | VAF 316/609 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs1554890228; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD7 | c.591+1G>C p.X197_splice | Splice Site (SNP) | VAF 102/271 reads (38%) | catalogued as COSV67159801, COSV67159994; called by muse, mutect2, varscan2
- BRD8 | c.18C>T p.G6= | Splice Region (SNP) | VAF 163/184 reads (89%) | catalogued as rs1211549881; called by muse, mutect2, varscan2
- C18orf21 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 161/386 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1394942587; called by muse, mutect2, varscan2
- C1orf198 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 186/423 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs775687288; called by muse, mutect2, varscan2
- C2CD4B | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 230/516 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.424); catalogued as rs757576566; called by muse, mutect2, varscan2
- C2orf81 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 405/795 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs1202437137; called by muse, mutect2, varscan2
- CAPN1 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 172/383 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374219289; called by muse, mutect2, varscan2
- CAVIN1 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 174/186 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CD101822; called by muse, mutect2, varscan2
- CIRBP | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 202/215 reads (94%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); catalogued as COSV58010357; called by muse, mutect2, varscan2
- COL20A1 | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 132/310 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs199598230, COSV58912614; called by muse, mutect2, varscan2
- COL8A2 | c.1675G>A p.G559R | Missense Mutation (SNP) | VAF 122/285 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1355298814; called by muse, mutect2, varscan2
- CPNE9 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 155/325 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs764893932; called by muse, mutect2, varscan2
- CSRNP3 | c.713G>C p.R238P | Missense Mutation (SNP) | VAF 180/473 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58775404; called by muse, mutect2, varscan2
- CXCL1 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 321/335 reads (96%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as rs745452423, COSV67611936; called by muse, mutect2, varscan2
- DENND5B | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs779402495, COSV60901345; called by muse, mutect2, varscan2
- DICER1 | c.4738C>T p.Q1580* | Nonsense Mutation (SNP) | VAF 187/445 reads (42%) | catalogued as COSV100602659; called by muse, mutect2, varscan2
- DIO2 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 139/320 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.543); catalogued as rs776352519, COSV101375905; called by muse, mutect2, varscan2
- DNAH11 | c.8749G>C p.V2917L | Missense Mutation (SNP) | VAF 46/733 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV100181557; called by muse, mutect2
- DNAI4 | c.872T>C p.M291T | Missense Mutation (SNP) | VAF 78/450 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1297625788; called by muse, mutect2, varscan2
- DZIP3 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 213/472 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs962450325; called by muse, mutect2, varscan2
- EPB41L4B | c.2578G>A p.V860I | Missense Mutation (SNP) | VAF 57/493 reads (12%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); catalogued as rs368177192; called by muse, mutect2, varscan2
- EPHA7 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 210/445 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65168876; called by muse, mutect2, varscan2
- ESYT3 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 182/381 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs756437673; called by muse, mutect2, varscan2
- FAM189A2 | c.256G>T p.V86F | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1230402200; called by muse, mutect2
- FAM193A | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 221/415 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs765452273; called by muse, mutect2, varscan2
- FGFBP3 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 335/837 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV61106407; called by muse, mutect2, varscan2
- GBA2 | c.2297G>A p.G766E | Missense Mutation (SNP) | VAF 82/88 reads (93%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.97); catalogued as rs1452391576; called by muse, mutect2, varscan2
- GK5 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 327/760 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); catalogued as rs777245025; called by muse, mutect2, varscan2
- GNL3L | c.189+1G>A p.X63_splice | Splice Site (SNP) | VAF 238/385 reads (62%) | catalogued as rs1182586091; called by muse, mutect2, varscan2
- HECTD4 | c.6803C>T p.A2268V | Missense Mutation (SNP) | VAF 241/521 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.087); catalogued as rs754811275; called by muse, mutect2, varscan2
- HSPBAP1 | c.764G>A p.W255* | Nonsense Mutation (SNP) | VAF 24/429 reads (6%) | catalogued as rs770067314, COSV100063326; called by muse, mutect2
- HYAL1 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 181/405 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782138855, COSV99807365; called by muse, mutect2, varscan2
- ITPKB | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 172/362 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as rs1162026389; called by muse, mutect2, varscan2
- KDM1B | c.1327A>G p.I443V (on ENST00000449850; = p.I311V on NM_153042.4) | Missense Mutation (SNP) | VAF 193/537 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371186294; called by muse, mutect2, varscan2
- KIAA0319L | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 177/420 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771251256; called by muse, mutect2, varscan2
- KIF1C | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 295/303 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100296950; called by muse, mutect2, varscan2
- KLRC2 | c.514T>C p.W172R | Missense Mutation (SNP) | VAF 133/167 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1229963815; called by muse, mutect2, varscan2
- LAT2 | c.448+2T>C p.X150_splice | Splice Site (SNP) | VAF 188/382 reads (49%) | catalogued as COSV51921007; called by muse, mutect2, varscan2
- LCAT | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 335/347 reads (97%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs775984613; called by muse, mutect2, varscan2
- LGR6 | c.1486G>A p.E496K (on ENST00000367278 / NM_001017403.1; = p.E444K on NM_021636.3) | Missense Mutation (SNP) | VAF 202/442 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as rs1457925301, COSV55154648; called by muse, mutect2, varscan2
- LOXHD1 | c.2228C>T p.T743I | Missense Mutation (SNP) | VAF 163/390 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs1200772160; called by muse, mutect2, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 164/318 reads (52%) | catalogued as rs746133895; called by mutect2, varscan2
- LY75 | c.2451A>G p.I817M | Missense Mutation (SNP) | VAF 154/365 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs766442692; called by muse, mutect2, varscan2
- LYPD3 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 407/678 reads (60%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs367798614; called by muse, mutect2, varscan2
- LYRM2 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 159/342 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs1382001616; called by muse, mutect2, varscan2
- MAST3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 35/280 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.267); catalogued as rs1287754393; called by mutect2, varscan2
- MEX3B | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 150/293 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.063); catalogued as rs1314872207, COSV100314219, COSV100314281; called by muse, mutect2, varscan2
- MICAL3 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 222/559 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1391541274; called by muse, mutect2, varscan2
- MTUS2 | c.1456C>A p.P486T | Missense Mutation (SNP) | VAF 195/385 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.083); catalogued as rs1027114751; called by muse, mutect2, varscan2
- NALCN | c.4937C>T p.T1646M | Missense Mutation (SNP) | VAF 149/329 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs771714484, COSV51951974, COSV51959231; called by muse, mutect2, varscan2
- NCOA1 | c.4096C>T p.L1366F | Missense Mutation (SNP) | VAF 163/350 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs753966380; called by muse, mutect2, varscan2
- NEK5 | c.1327A>G p.R443G | Missense Mutation (SNP) | VAF 133/310 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV62880508; called by muse, mutect2, varscan2
- NRDE2 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 169/413 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs776078489, COSV100583426; called by muse, mutect2, varscan2
- OR1L1 | c.251T>C p.I84T (on ENST00000373686; = p.I34T on NM_001005236.3) | Missense Mutation (SNP) | VAF 167/396 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs771915010; called by muse, mutect2, varscan2
- OR4C3 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 186/445 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as rs146835532; called by muse, mutect2, varscan2
- OR9A2 | c.669G>C p.K223N | Missense Mutation (SNP) | VAF 320/691 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV63306896; called by muse, mutect2, varscan2
- PIGB | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 212/408 reads (52%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs1191317490; called by muse, mutect2, varscan2
- PKDCC | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 206/466 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as rs776740396, COSV54307336; called by muse, mutect2, varscan2
- PLS1 | c.1179A>G p.G393= | Splice Region (SNP) | VAF 143/356 reads (40%) | catalogued as rs1472586536; called by muse, mutect2, varscan2
- POSTN | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 172/384 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs149175978; called by muse, mutect2, varscan2
- PYCARD | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 174/182 reads (96%) | catalogued as COSV56008290; called by muse, mutect2, varscan2
- RC3H2 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 192/441 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV59016035; called by muse, mutect2, varscan2
- RELN | c.3781G>A p.E1261K | Missense Mutation (SNP) | VAF 216/486 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV58995002; called by muse, mutect2, varscan2
- RET | c.615G>T p.R205S | Missense Mutation (SNP) | VAF 159/218 reads (73%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV100393537; called by muse, mutect2, varscan2
- RNF6 | c.1139A>G p.E380G | Missense Mutation (SNP) | VAF 232/513 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1165969274; called by muse, mutect2, varscan2
- RYR3 | c.7072C>T p.P2358S (on ENST00000389232; = p.P2359S on NM_001036.6) | Missense Mutation (SNP) | VAF 194/439 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66781318; called by muse, mutect2, varscan2
- SEPTIN9 | c.1453C>T p.R485W (on ENST00000427177 / NM_001113491.2; = p.R467W on NM_006640.4) | Missense Mutation (SNP) | VAF 145/151 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1348107506, COSV100217638; called by muse, mutect2, varscan2
- SHB | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 123/128 reads (96%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1266070968; called by muse, mutect2, varscan2
- SLC38A2 | c.1182C>T p.I394= | Splice Region (SNP) | VAF 102/246 reads (41%) | catalogued as rs776603868; called by muse, mutect2, varscan2
- SLC44A5 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 257/505 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs779526816; called by muse, mutect2, varscan2
- SNRNP35 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 221/444 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV63471842; called by muse, mutect2, varscan2
- SNX27 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 154/339 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV64327229; called by muse, mutect2, varscan2
- SPSB3 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 173/178 reads (97%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs376832134; called by muse, mutect2, varscan2
- SYNE1 | c.3943C>T p.R1315W (on ENST00000367255 / NM_182961.4; = p.R1322W on NM_033071.3) | Missense Mutation (SNP) | VAF 200/428 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs747574901, COSV55009720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNPR | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 161/344 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.498); catalogued as rs1168463825, COSV55732557; called by muse, mutect2, varscan2
- TNNI1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 185/369 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs1224369349; called by muse, mutect2, varscan2
- TPRKB | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as rs778172082; called by muse, mutect2, varscan2
- UBQLN2 | c.1583C>T p.T528I | Missense Mutation (SNP) | VAF 182/289 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV57740305; called by muse, mutect2, varscan2
- UNKL | c.1939T>C p.S647P (on ENST00000389221 / NM_001372107.1; = p.S143P on NM_001276414.2) | Missense Mutation (SNP) | VAF 151/155 reads (97%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752935187; called by muse, mutect2, varscan2
- WDR75 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 195/464 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100133993, COSV100134070; called by muse, mutect2, varscan2
- YIF1B | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 158/460 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs978986846; called by muse, mutect2, varscan2
- ZC3H11A | c.1453G>A p.V485M | Missense Mutation (SNP) | VAF 393/853 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0.029); catalogued as rs764942220; called by muse, mutect2, varscan2
- ZNF273 | c.1637G>C p.R546T | Missense Mutation (SNP) | VAF 117/260 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100139608; called by muse, mutect2, varscan2
- ADGRA3 | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 123/283 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ANKRD13B | c.756-3C>T | Splice Region (SNP) | VAF 329/353 reads (93%) | called by muse, mutect2, varscan2
- ANKRD63 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 128/248 reads (52%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- AP2A1 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 199/631 reads (32%) | called by muse, mutect2, varscan2
- ARNTL2 | c.52A>G p.N18D | Missense Mutation (SNP) | VAF 112/121 reads (93%) | SIFT tolerated (0.63); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ARVCF | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 188/359 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ATP2C1 | c.1648A>G p.T550A | Missense Mutation (SNP) | VAF 206/486 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP5PB | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 231/510 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- B3GNT8 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 147/518 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- BCKDHB | c.1105C>G p.H369D | Missense Mutation (SNP) | VAF 143/386 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BCR | c.3564-1G>A p.X1188_splice | Splice Site (SNP) | VAF 96/416 reads (23%) | called by muse, varscan2
- BCR | c.3577_3591del p.E1193_K1197del | In Frame Del (DEL) | VAF 102/444 reads (23%) | called by pindel, varscan2
- BRDT | c.1081A>G p.M361V | Missense Mutation (SNP) | VAF 273/529 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BSN | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 242/527 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C6 | c.2027T>A p.F676Y | Missense Mutation (SNP) | VAF 410/425 reads (96%) | SIFT tolerated (0.27); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- CCDC106 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 173/531 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK11A | c.70A>G p.K24E | Missense Mutation (SNP) | VAF 294/662 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CEACAM7 | c.144del p.K49Rfs*5 | Frame Shift Del (DEL) | VAF 110/424 reads (26%) | called by pindel, varscan2
- CENPV | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2
- CHD9 | c.1229T>C p.L410P | Missense Mutation (SNP) | VAF 222/438 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- CLK4 | c.763T>C p.F255L | Missense Mutation (SNP) | VAF 204/213 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLSTN2 | c.1304A>G p.D435G | Missense Mutation (SNP) | VAF 186/387 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- COG8 | c.377+8G>A | Splice Region (SNP) | VAF 24/470 reads (5%) | called by muse, mutect2
- COL7A1 | c.4819G>A p.G1607S | Missense Mutation (SNP) | VAF 147/348 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CREBBP | c.3673G>C p.A1225P | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CRLF1 | c.114C>T p.A38= | Splice Region (SNP) | VAF 170/310 reads (55%) | called by muse, mutect2, varscan2
- CSNK2A2 | c.287T>C p.I96T | Missense Mutation (SNP) | VAF 201/214 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CTNNBL1 | c.1604A>G p.E535G | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.38); called by muse, mutect2
- CTTNBP2 | c.3958T>C p.S1320P | Missense Mutation (SNP) | VAF 289/660 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DBNL | c.874C>T p.Q292* (on ENST00000448521 / NM_001014436.3; = p.Q293* on NM_014063.7) | Nonsense Mutation (SNP) | VAF 179/405 reads (44%) | called by muse, mutect2, varscan2
- DDI1 | c.110A>G p.E37G | Missense Mutation (SNP) | VAF 205/453 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHCR7 | c.845T>C p.I282T | Missense Mutation (SNP) | VAF 280/544 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DLX3 | c.166T>C p.Y56H | Missense Mutation (SNP) | VAF 111/116 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- DMTN | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 145/153 reads (95%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- DNAJC11 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 266/497 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- DPY19L1 | c.1867T>C p.S623P | Missense Mutation (SNP) | VAF 169/392 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- EBF4 | c.1055G>A p.R352K (on ENST00000609451; = p.R348K on NM_001110514.1) | Missense Mutation (SNP) | VAF 117/1056 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- EFHB | c.1741A>G p.I581V | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- EGR2 | c.1417A>G p.T473A | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ELOVL1 | c.376-6T>C | Splice Region (SNP) | VAF 240/373 reads (64%) | called by muse, mutect2, varscan2
- EMC10 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 229/388 reads (59%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EPAS1 | c.760T>C p.F254L | Missense Mutation (SNP) | VAF 221/507 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- EPHA2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 127/257 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVA1B | c.179G>C p.R60P | Missense Mutation (SNP) | VAF 91/485 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EXD1 | c.967A>G p.R323G | Missense Mutation (SNP) | VAF 165/384 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EXOC6B | c.2248G>A p.G750S | Missense Mutation (SNP) | VAF 256/625 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM160B1 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 268/483 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- FBLIM1 | c.764T>C p.I255T | Missense Mutation (SNP) | VAF 275/580 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FHL3 | c.331+5G>A | Splice Region (SNP) | VAF 130/320 reads (41%) | called by muse, mutect2, varscan2
- FHL5 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 142/338 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FMNL3 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 214/424 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FRMD3 | c.49A>G p.M17V | Missense Mutation (SNP) | VAF 282/561 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- FUT11 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 269/391 reads (69%) | called by muse, mutect2, varscan2
- FUT7 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 169/387 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GDF9 | c.1328A>G p.Y443C | Missense Mutation (SNP) | VAF 125/133 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GHDC | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 258/267 reads (97%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GLB1L | c.1481T>C p.L494S | Missense Mutation (SNP) | VAF 171/379 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- GLDC | c.2762A>G p.D921G | Missense Mutation (SNP) | VAF 220/494 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- GOLGA4 | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 260/515 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GOLGA8N | c.443A>G p.D148G | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- GPATCH1 | c.767A>C p.N256T | Missense Mutation (SNP) | VAF 34/698 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2
- GPC1 | c.1181T>C p.I394T | Missense Mutation (SNP) | VAF 201/403 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GPR182 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 210/487 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR39 | c.1073T>C p.V358A | Missense Mutation (SNP) | VAF 260/568 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- HELZ2 | c.3271G>A p.E1091K (on ENST00000467148 / NM_001037335.2; = p.E522K on NM_033405.3) | Missense Mutation (SNP) | VAF 194/372 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- HEPHL1 | c.3355C>A p.L1119I | Missense Mutation (SNP) | VAF 191/429 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- HEPHL1 | c.3356T>C p.L1119P | Missense Mutation (SNP) | VAF 196/432 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- IFNGR1 | c.193A>T p.N65Y | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- IGF1 | c.530A>G p.E177G | Missense Mutation (SNP) | VAF 364/777 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- IGSF22 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 215/455 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IL17RC | c.389C>T p.P130L (on ENST00000295981 / NM_153461.4; = p.P59L on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 227/513 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- INF2 | c.986-1G>A p.X329_splice | Splice Site (SNP) | VAF 245/455 reads (54%) | called by muse, mutect2, varscan2
- INPP4A | c.911C>T p.T304I | Missense Mutation (SNP) | VAF 291/538 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- IRX5 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.253); called by muse, mutect2
- JAK3 | c.567-7C>A | Splice Region (SNP) | VAF 196/298 reads (66%) | called by muse, mutect2, varscan2
- KHDC4 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 196/440 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF21B | c.3132G>A p.K1044= | Splice Region (SNP) | VAF 165/432 reads (38%) | called by muse, mutect2, varscan2
- KMT2B | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 167/560 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT12 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 237/246 reads (96%) | SIFT tolerated (0.06); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- LOXL1 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- LPIN1 | c.2249G>A p.G750E | Missense Mutation (SNP) | VAF 178/399 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRN4 | c.1054T>C p.S352P | Missense Mutation (SNP) | VAF 733/845 reads (87%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTB4R | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 205/448 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- LY75 | c.1717A>G p.T573A | Missense Mutation (SNP) | VAF 198/411 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by mutect2, varscan2
- MESP1 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 122/219 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2
- MFSD14B | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 128/293 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.16); called by muse, varscan2
- MFSD14B | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 126/300 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGAT4C | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 218/478 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MIDEAS | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 192/521 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MIP | c.606G>A p.W202* | Nonsense Mutation (SNP) | VAF 168/336 reads (50%) | called by muse, mutect2, varscan2
- MRPL2 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 256/267 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- MUC12 | c.2639A>G p.E880G (on ENST00000379442; = p.E737G on NM_001164462.1) | Missense Mutation (SNP) | VAF 73/438 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- MXRA5 | c.7685T>C p.L2562P | Missense Mutation (SNP) | VAF 185/216 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NADSYN1 | c.85+2T>C p.X29_splice | Splice Site (SNP) | VAF 139/298 reads (47%) | called by muse, mutect2, varscan2
- NAV1 | c.1222A>C p.T408P | Missense Mutation (SNP) | VAF 41/368 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- NBPF26 | c.4322A>C p.Q1441P (on ENST00000620612; = p.Q1179P on NM_001351372.1) | Missense Mutation (SNP) | VAF 304/680 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- NCOA5 | c.1624A>G p.K542E | Missense Mutation (SNP) | VAF 117/238 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NEK1 | c.1571G>A p.G524E | Missense Mutation (SNP) | VAF 209/213 reads (98%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- NFATC4 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 117/234 reads (50%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NFKBIZ | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 144/328 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- NIPAL1 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 238/495 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NKD2 | c.85T>C p.Y29H | Missense Mutation (SNP) | VAF 1219/1237 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- NYNRIN | c.4262T>C p.L1421P | Missense Mutation (SNP) | VAF 124/333 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- OR10J4 | c.506T>C p.F169S | Missense Mutation (SNP) | VAF 277/573 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR6X1 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 97/227 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OSBP2 | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 112/123 reads (91%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAPPA2 | c.1694G>A p.W565* | Nonsense Mutation (SNP) | VAF 276/586 reads (47%) | called by muse, mutect2, varscan2
- PARP1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 186/464 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAXX | c.180+2T>C p.X60_splice | Splice Site (SNP) | VAF 194/427 reads (45%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.871C>G p.R291G | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.592); called by muse, mutect2
- PCNX1 | c.2414del p.P805Lfs*10 | Frame Shift Del (DEL) | VAF 80/228 reads (35%) | called by mutect2, pindel, varscan2
- PHACTR2 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 211/476 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PHC3 | c.889T>C p.Y297H (on ENST00000494943 / NM_001308116.2; = p.Y309H on NM_024947.4) | Missense Mutation (SNP) | VAF 192/445 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PIK3CD | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 240/680 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PLAAT5 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 175/375 reads (47%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLD2 | c.597C>G p.D199E | Missense Mutation (SNP) | VAF 545/563 reads (97%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POLR2A | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 257/267 reads (96%) | SIFT tolerated (0.4); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- POLR3B | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 275/637 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POTEH | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PPP1R14B | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 140/334 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PRKAB2 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 67/530 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSAT1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 249/567 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPN18 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 264/594 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPN7 | c.395C>T p.P132L (on ENST00000495688; = p.P171L on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/229 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- PTPRE | c.1009G>T p.A337S | Missense Mutation (SNP) | VAF 69/671 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PTPRQ | c.1331A>G p.D444G (on ENST00000616559; = p.D402G on NM_001145026.2) | Missense Mutation (SNP) | VAF 105/224 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RABGGTA | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 145/336 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- RALGAPB | c.3657dup p.S1220Vfs*3 | Frame Shift Ins (INS) | VAF 198/527 reads (38%) | called by mutect2, pindel, varscan2
- RASA1 | c.1147_1149dup p.P383dup | In Frame Ins (INS) | VAF 42/175 reads (24%) | called by mutect2, pindel, varscan2
- RAVER1 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 153/158 reads (97%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RCN3 | c.879G>A p.K293= | Splice Region (SNP) | VAF 276/469 reads (59%) | called by muse, mutect2, varscan2
- RET | c.614G>C p.R205T | Missense Mutation (SNP) | VAF 165/226 reads (73%) | SIFT tolerated (0.32); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- RGPD8 | c.4769G>A p.S1590N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by mutect2, varscan2
- RICTOR | c.667A>G p.I223V | Missense Mutation (SNP) | VAF 381/393 reads (97%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- ROS1 | c.3739A>T p.N1247Y | Missense Mutation (SNP) | VAF 51/560 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- SEC63 | c.607_617del p.I203Cfs*13 | Frame Shift Del (DEL) | VAF 102/359 reads (28%) | called by mutect2, pindel, varscan2
- SETX | c.1852T>C p.S618P | Missense Mutation (SNP) | VAF 222/444 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SHC3 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 95/206 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SHPK | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 497/510 reads (97%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SLC25A3 | c.310T>C p.F104L (on ENST00000228318 / NM_005888.3; = p.F103L on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 133/294 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC25A35 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC7A4 | c.179del p.G60Vfs*231 | Frame Shift Del (DEL) | VAF 158/345 reads (46%) | called by mutect2, pindel, varscan2
- SMNDC1 | c.255A>T p.E85D | Missense Mutation (SNP) | VAF 109/327 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOGA1 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 204/454 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOGA1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 348/771 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STK32C | c.17A>G p.E6G | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- STK36 | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 206/620 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.04); called by muse, mutect2
- STOM | c.503A>G p.E168G | Missense Mutation (SNP) | VAF 212/490 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- STX5 | c.296A>G p.K99R | Missense Mutation (SNP) | VAF 219/531 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SUGP2 | c.2450+2T>A p.X817_splice | Splice Site (SNP) | VAF 111/287 reads (39%) | called by muse, mutect2, varscan2
- SYBU | c.1808G>A p.W603* (on ENST00000276646 / NM_001099754.2; = p.W602* on NM_017786.6) | Nonsense Mutation (SNP) | VAF 208/380 reads (55%) | called by muse, mutect2, varscan2
- SYNCRIP | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 186/414 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- SYNE1 | c.2575T>G p.L859V (on ENST00000367255 / NM_182961.4; = p.L866V on NM_033071.3) | Missense Mutation (SNP) | VAF 120/262 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TACC1 | c.1753G>A p.V585M | Missense Mutation (SNP) | VAF 141/151 reads (93%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- TAS2R19 | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 206/218 reads (94%) | SIFT tolerated (0.18); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- TBCB | c.549T>C p.G183= | Splice Region (SNP) | VAF 188/299 reads (63%) | called by muse, mutect2, varscan2
- TBCCD1 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 153/386 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TGFB1 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 356/549 reads (65%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THBS3 | c.1351A>G p.N451D | Missense Mutation (SNP) | VAF 136/276 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.071); called by muse, varscan2
- TIMD4 | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 232/239 reads (97%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TJP2 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 128/318 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2
- TMA7 | c.17-1G>A p.X6_splice | Splice Site (SNP) | VAF 292/673 reads (43%) | called by muse, mutect2, varscan2
- TMC1 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 248/521 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- TMCC1 | c.980A>G p.Q327R (on ENST00000393238 / NM_001349268.2; = p.Q3R on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 198/432 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TMED8 | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 171/328 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TMEM165 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 240/247 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM178A | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 37/468 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.324); called by muse, mutect2
- TOPAZ1 | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 43/414 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM55 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 76/900 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- TRIP11 | c.4931A>G p.Q1644R | Missense Mutation (SNP) | VAF 238/457 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPM4 | c.682A>C p.N228H | Missense Mutation (SNP) | VAF 254/443 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- TUBB8 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.029); called by muse, mutect2
- TWNK | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 174/467 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TXNRD1 | c.1637A>T p.E546V (on ENST00000525566 / NM_001093771.3; = p.E448V on NM_003330.4) | Missense Mutation (SNP) | VAF 116/232 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- UPF2 | c.1547A>G p.D516G | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- USP47 | c.596T>C p.L199S (on ENST00000399455 / NM_001372095.1; = p.L111S on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13D | c.963del p.F321Lfs*3 | Frame Shift Del (DEL) | VAF 123/399 reads (31%) | called by mutect2, pindel, varscan2
- VRK2 | c.136+2T>C p.X46_splice | Splice Site (SNP) | VAF 71/166 reads (43%) | called by muse, mutect2, varscan2
- WDR38 | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 174/355 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF133 | c.509C>T p.P170L (on ENST00000316358 / NM_001352454.2; = p.P169L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 642/839 reads (77%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF148 | c.583+1G>A p.X195_splice | Splice Site (SNP) | VAF 166/376 reads (44%) | called by muse, mutect2, varscan2
- ZNF281 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 209/438 reads (48%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZNF408 | c.1916C>G p.S639C | Missense Mutation (SNP) | VAF 361/733 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF667 | c.1576C>G p.P526A | Missense Mutation (SNP) | VAF 175/294 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF763 | c.4-8T>C | Splice Region (SNP) | VAF 89/226 reads (39%) | called by muse, mutect2, varscan2
- ZNF772 | c.970T>C p.C324R | Missense Mutation (SNP) | VAF 330/1010 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA13 | c.4125A>G p.L1375= | Silent (SNP) | VAF 226/523 reads (43%) | called by muse, mutect2, varscan2
- ACHE | c.375G>A p.E125= | Silent (SNP) | VAF 152/334 reads (46%) | catalogued as COSV53818775; called by muse, mutect2, varscan2
- ACOT8 | c.84C>T p.V28= | Silent (SNP) | VAF 285/536 reads (53%) | called by muse, mutect2, varscan2
- AKAP13 | c.1104C>T p.S368= | Silent (SNP) | VAF 242/492 reads (49%) | catalogued as rs1239280217; called by muse, mutect2, varscan2
- ANK1 | c.1977C>T p.A659= | Silent (SNP) | VAF 168/176 reads (95%) | catalogued as rs933890479; called by muse, mutect2, varscan2
- ARFGEF1 | c.4440C>T p.D1480= | Silent (SNP) | VAF 311/594 reads (52%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.558C>T p.Y186= | Silent (SNP) | VAF 124/426 reads (29%) | catalogued as rs577018777, COSV61529726; called by muse, mutect2, varscan2
- ASXL1 | c.672C>T p.T224= | Silent (SNP) | VAF 299/582 reads (51%) | called by muse, mutect2, varscan2
- AVIL | c.192G>A p.G64= | Silent (SNP) | VAF 158/339 reads (47%) | called by muse, mutect2, varscan2
- BACH2 | c.591C>T p.I197= | Silent (SNP) | VAF 115/224 reads (51%) | catalogued as rs755392753; called by muse, mutect2, varscan2
- CD300LG | c.546T>C p.P182= | Silent (SNP) | VAF 206/215 reads (96%) | called by muse, mutect2, varscan2
- CDC42BPB | c.1395C>T p.T465= | Silent (SNP) | VAF 198/495 reads (40%) | catalogued as rs200614410; called by muse, mutect2, varscan2
- CENPP | c.273T>C p.T91= | Silent (SNP) | VAF 147/321 reads (46%) | called by muse, mutect2, varscan2
- CNBD2 | c.1494G>A p.R498= (on ENST00000373973 / NM_001365709.1; = p.R494= on NM_080834.4) | Silent (SNP) | VAF 325/735 reads (44%) | called by muse, mutect2, varscan2
- CPT1A | c.1473T>C p.I491= | Silent (SNP) | VAF 105/202 reads (52%) | called by muse, mutect2, varscan2
- CYFIP1 | c.480A>G p.T160= | Silent (SNP) | VAF 161/381 reads (42%) | catalogued as rs759007201; called by muse, mutect2, varscan2
- DDRGK1 | c.858G>A p.R286= | Silent (SNP) | VAF 1375/1550 reads (89%) | called by muse, mutect2, varscan2
- DOK1 | c.855C>T p.P285= | Silent (SNP) | VAF 200/457 reads (44%) | called by muse, mutect2, varscan2
- DPP3 | c.891C>T p.S297= | Silent (SNP) | VAF 127/289 reads (44%) | called by muse, mutect2, varscan2
- DSEL | c.1188C>T p.H396= | Silent (SNP) | VAF 127/283 reads (45%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.2583C>T p.A861= | Silent (SNP) | VAF 98/236 reads (42%) | called by muse, mutect2, varscan2
- FAM171A2 | c.2082G>A p.E694= | Silent (SNP) | VAF 116/122 reads (95%) | catalogued as rs1356093680; called by muse, mutect2, varscan2
- FASN | c.6433C>T p.L2145= | Silent (SNP) | VAF 289/302 reads (96%) | catalogued as rs1398009096; called by muse, mutect2, varscan2
- FBXL14 | c.433C>T p.L145= | Silent (SNP) | VAF 189/200 reads (95%) | called by muse, mutect2, varscan2
- FLNB | c.2895C>T p.T965= | Silent (SNP) | VAF 226/518 reads (44%) | catalogued as rs748235033, COSV55873832; called by muse, mutect2, varscan2
- FZD4 | c.546C>T p.H182= | Silent (SNP) | VAF 118/272 reads (43%) | catalogued as rs756589557; called by muse, mutect2, varscan2
- GAS1 | c.6G>A p.V2= | Silent (SNP) | VAF 163/386 reads (42%) | called by muse, mutect2, varscan2
- GRIA3 | c.192C>T p.T64= | Silent (SNP) | VAF 291/304 reads (96%) | called by muse, mutect2, varscan2
- HAVCR1 | c.723A>C p.T241= | Silent (SNP) | VAF 176/181 reads (97%) | called by muse, mutect2, varscan2
- HPCAL4 | c.522A>G p.A174= | Silent (SNP) | VAF 293/595 reads (49%) | called by muse, mutect2, varscan2
- IFITM10 | c.657C>T p.I219= | Silent (SNP) | VAF 298/624 reads (48%) | called by muse, mutect2, varscan2
- IKZF2 | c.579T>C p.G193= | Silent (SNP) | VAF 208/418 reads (50%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2124T>C p.R708= | Silent (SNP) | VAF 505/777 reads (65%) | called by muse, mutect2, varscan2
- KBTBD6 | c.1770T>C p.I590= | Silent (SNP) | VAF 164/347 reads (47%) | catalogued as rs1046834123; called by muse, mutect2, varscan2
- KCNA3 | c.480C>T p.L160= | Silent (SNP) | VAF 230/610 reads (38%) | catalogued as rs768715706; called by muse, mutect2, varscan2
- KCTD8 | c.666C>T p.D222= | Silent (SNP) | VAF 387/758 reads (51%) | catalogued as rs1336007646; called by muse, mutect2, varscan2
- KIF14 | c.4413T>C p.F1471= | Silent (SNP) | VAF 31/233 reads (13%) | called by muse, mutect2, varscan2
- LCA5 | c.1131A>G p.G377= | Silent (SNP) | VAF 145/323 reads (45%) | catalogued as rs149412524; called by muse, mutect2, varscan2
- LENG1 | c.240G>A p.R80= | Silent (SNP) | VAF 319/500 reads (64%) | called by muse, mutect2, varscan2
- LIMS1 | c.519G>A p.R173= | Silent (SNP) | VAF 308/533 reads (58%) | called by muse, mutect2, varscan2
- LMBRD2 | c.66T>C p.H22= | Silent (SNP) | VAF 458/469 reads (98%) | called by muse, mutect2, varscan2
- MAP3K4 | c.4725G>A p.K1575= | Silent (SNP) | VAF 180/345 reads (52%) | called by muse, mutect2, varscan2
- MAPKAP1 | c.367C>T p.L123= | Silent (SNP) | VAF 119/290 reads (41%) | called by muse, mutect2, varscan2
- MAT2A | c.1146G>A p.R382= | Silent (SNP) | VAF 231/502 reads (46%) | called by muse, mutect2, varscan2
- MEX3C | c.702G>A p.E234= | Silent (SNP) | VAF 267/504 reads (53%) | called by muse, mutect2, varscan2
- MFSD1 | c.546A>G p.R182= | Silent (SNP) | VAF 204/422 reads (48%) | called by muse, varscan2
- MGA | c.8295G>A p.G2765= (on ENST00000219905 / NM_001164273.1; = p.G2556= on NM_001080541.2) | Silent (SNP) | VAF 204/370 reads (55%) | catalogued as rs777877908; called by muse, mutect2, varscan2
- MICALL2 | c.2211G>A p.P737= | Silent (SNP) | VAF 117/243 reads (48%) | catalogued as rs529462236; called by muse, mutect2, varscan2
- MROH1 | c.93C>T p.A31= | Silent (SNP) | VAF 225/595 reads (38%) | catalogued as rs1304356089; called by muse, mutect2, varscan2
- MTO1 | c.1896T>C p.A632= (on ENST00000370300 / NM_133645.3; = p.A607= on NM_012123.4) | Silent (SNP) | VAF 233/494 reads (47%) | called by muse, mutect2, varscan2
- MUC16 | c.11280C>A p.P3760= | Silent (SNP) | VAF 206/214 reads (96%) | catalogued as COSV67475999, COSV67483502; called by muse, mutect2
- MYH11 | c.3264G>A p.K1088= | Silent (SNP) | VAF 243/255 reads (95%) | catalogued as COSV100260302; called by muse, mutect2, varscan2
- NCOA1 | c.4095C>T p.G1365= | Silent (SNP) | VAF 161/329 reads (49%) | called by muse, mutect2, varscan2
- NCOA2 | c.1560C>T p.C520= | Silent (SNP) | VAF 184/491 reads (37%) | catalogued as COSV101476050; called by muse, mutect2, varscan2
- NFE2L1 | c.1491T>C p.S497= | Silent (SNP) | VAF 171/180 reads (95%) | called by muse, mutect2, varscan2
- NPR1 | c.1443C>T p.L481= | Silent (SNP) | VAF 188/450 reads (42%) | called by muse, mutect2, varscan2
- NVL | c.2217C>T p.R739= | Silent (SNP) | VAF 118/282 reads (42%) | catalogued as rs1297042044; called by muse, mutect2, varscan2
- OS9 | c.1542G>A p.K514= | Silent (SNP) | VAF 343/649 reads (53%) | catalogued as COSV99067173; called by muse, mutect2, varscan2
- POLR2J3 | c.33G>A p.L11= | Silent (SNP) | VAF 157/1262 reads (12%) | catalogued as rs768576402; called by muse, mutect2, varscan2
- PPFIA4 | c.1612T>C p.L538= (on ENST00000447715; = p.L513= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 169/387 reads (44%) | called by muse, mutect2, varscan2
- PPP1R26 | c.189C>T p.T63= | Silent (SNP) | VAF 116/254 reads (46%) | called by muse, mutect2, varscan2
- PPP1R37 | c.1236C>T p.A412= | Silent (SNP) | VAF 400/667 reads (60%) | called by muse, mutect2, varscan2
- PPP3CC | c.57C>T p.P19= | Silent (SNP) | VAF 92/94 reads (98%) | catalogued as COSV51501116; called by muse, mutect2, varscan2
- PTPRQ | c.1290T>C p.I430= (on ENST00000616559; = p.I388= on NM_001145026.2) | Silent (SNP) | VAF 26/340 reads (8%) | called by muse, mutect2
- RAPGEF5 | c.201T>C p.S67= | Silent (SNP) | VAF 163/359 reads (45%) | catalogued as COSV59794415; called by muse, mutect2, varscan2
- RPS6KA1 | c.21G>A p.K7= | Silent (SNP) | VAF 169/333 reads (51%) | called by muse, mutect2, varscan2
- SCAP | c.2019G>A p.Q673= | Silent (SNP) | VAF 240/515 reads (47%) | called by muse, mutect2, varscan2
- SCARF2 | c.2454C>T p.A818= | Silent (SNP) | VAF 121/241 reads (50%) | catalogued as rs1249994378; called by muse, mutect2, varscan2
- SH2D2A | c.963C>T p.V321= | Silent (SNP) | VAF 198/439 reads (45%) | called by muse, mutect2, varscan2
- SHC1 | c.126G>A p.L42= | Silent (SNP) | VAF 343/748 reads (46%) | called by muse, mutect2, varscan2
- SLC7A9 | c.297C>T p.Y99= | Silent (SNP) | VAF 112/560 reads (20%) | called by muse, mutect2, varscan2
- SMPDL3B | c.948G>A p.G316= | Silent (SNP) | VAF 215/547 reads (39%) | called by muse, mutect2, varscan2
- SNAPC4 | c.1341A>G p.L447= | Silent (SNP) | VAF 26/408 reads (6%) | called by muse, mutect2
- SPTBN2 | c.5364G>A p.E1788= | Silent (SNP) | VAF 286/611 reads (47%) | called by muse, mutect2, varscan2
- SVEP1 | c.8301C>T p.S2767= | Silent (SNP) | VAF 118/312 reads (38%) | catalogued as COSV52840167; called by muse, mutect2
- SYNE2 | c.4200A>G p.E1400= | Silent (SNP) | VAF 215/537 reads (40%) | called by muse, mutect2, varscan2
- TANC1 | c.4977C>T p.S1659= | Silent (SNP) | VAF 266/652 reads (41%) | catalogued as rs1449272821, COSV55090848; called by muse, mutect2, varscan2
- TCAF1 | c.2442C>T p.Y814= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs1486093207; called by mutect2, varscan2
- TNK1 | c.1374C>T p.T458= (on ENST00000576812 / NM_001251902.2; = p.T453= on NM_003985.5) | Silent (SNP) | VAF 255/268 reads (95%) | catalogued as rs571670663; called by muse, mutect2, varscan2
- TRAF4 | c.1218G>A p.E406= | Silent (SNP) | VAF 301/312 reads (96%) | called by muse, mutect2, varscan2
- TRPM5 | c.2373G>A p.E791= | Silent (SNP) | VAF 272/609 reads (45%) | catalogued as rs1307737844; called by muse, mutect2, varscan2
- TSPAN32 | c.145C>T p.L49= | Silent (SNP) | VAF 202/460 reads (44%) | catalogued as COSV99477988; called by muse, mutect2, varscan2
- TTC7A | c.2139C>T p.I713= | Silent (SNP) | VAF 145/335 reads (43%) | called by muse, mutect2, varscan2
- TTF1 | c.480C>T p.H160= | Silent (SNP) | VAF 191/420 reads (45%) | called by muse, mutect2, varscan2
- ZC3H3 | c.1230C>T p.V410= | Silent (SNP) | VAF 178/321 reads (55%) | called by muse, mutect2, varscan2
- ZMYND8 | c.2856T>C p.T952= (on ENST00000311275 / NM_001363741.2; = p.T926= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 210/465 reads (45%) | called by muse, mutect2, varscan2
- ZNF540 | c.1845C>T p.A615= | Silent (SNP) | VAF 29/43 reads (67%) | catalogued as COSV57108285; called by muse, mutect2, varscan2
- ZNF609 | c.2175G>A p.K725= | Silent (SNP) | VAF 224/445 reads (50%) | called by muse, mutect2, varscan2
- ZNF609 | c.3483G>A p.E1161= | Silent (SNP) | VAF 125/315 reads (40%) | catalogued as rs149250735; called by muse, mutect2, varscan2
- ZNF804B | c.3663T>C p.A1221= | Silent (SNP) | VAF 310/588 reads (53%) | called by muse, mutect2, varscan2
- ZNF836 | c.582A>G p.K194= | Silent (SNP) | VAF 325/502 reads (65%) | catalogued as rs766865959; called by muse, mutect2, varscan2
- ABCA2 | c.250+367C>T | Intron (SNP) | VAF 178/364 reads (49%) | catalogued as rs1424685385; called by muse, mutect2, varscan2
- AC053503.6 | c.750-21G>A | Intron (SNP) | VAF 81/131 reads (62%) | called by muse, mutect2, varscan2
- ADPRHL1 | c.*81G>A | 3'UTR (SNP) | VAF 50/53 reads (94%) | called by muse, mutect2, varscan2
- AHCTF1 | c.-70C>T | 5'UTR (SNP) | VAF 129/330 reads (39%) | called by muse, mutect2, varscan2
- AIFM3 | c.1652+56G>A | Intron (SNP) | VAF 50/132 reads (38%) | called by muse, mutect2, varscan2
- AKAP8 | c.371+23C>T | Intron (SNP) | VAF 70/137 reads (51%) | called by muse, mutect2, varscan2
- ALOX15B | c.572+11C>T | Intron (SNP) | VAF 202/210 reads (96%) | called by muse, mutect2, varscan2
- ARL6IP4 | c.*87C>T | 3'UTR (SNP) | VAF 82/146 reads (56%) | called by muse, mutect2, varscan2
- ARMC12 | c.164-14G>A | Intron (SNP) | VAF 102/105 reads (97%) | called by muse, mutect2, varscan2
- ATF3 | c.349-286G>A | Intron (SNP) | VAF 145/304 reads (48%) | catalogued as rs1396675709; called by muse, mutect2, varscan2
- ATG16L2 | c.1366+75C>T | Intron (SNP) | VAF 50/86 reads (58%) | called by muse, mutect2, varscan2
- ATPAF1 | c.-21G>A | 5'UTR (SNP) | VAF 310/742 reads (42%) | called by muse, mutect2, varscan2
- BAIAP2L1 | c.1163+34C>T | Intron (SNP) | VAF 76/159 reads (48%) | catalogued as rs766062967; called by muse, mutect2, varscan2
- CASP4 | c.372+32A>T | Intron (SNP) | VAF 83/174 reads (48%) | called by muse, mutect2, varscan2
- CATIP | c.833-83G>A | Intron (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- CDH9 | c.999+99C>T | Intron (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- CEP43 | chr6:166999349 G>A | 5'Flank (SNP) | VAF 29/49 reads (59%) | called by muse, mutect2, varscan2
- CERS5 | c.304-45G>A | Intron (SNP) | VAF 55/132 reads (42%) | called by muse, mutect2
- CFAP36 | c.115+522G>A | Intron (SNP) | VAF 142/324 reads (44%) | called by muse, mutect2, varscan2
- CLDN3 | c.-35A>G | 5'UTR (SNP) | VAF 49/104 reads (47%) | catalogued as rs1554626787; called by muse, mutect2, varscan2
- COA5 | c.-79G>A | 5'UTR (SNP) | VAF 51/155 reads (33%) | called by muse, mutect2, varscan2
- COL16A1 | c.3195+29C>T | Intron (SNP) | VAF 196/453 reads (43%) | called by muse, mutect2, varscan2
- COLQ | c.107-8895G>A | Intron (SNP) | VAF 242/570 reads (42%) | catalogued as rs1448908843; called by muse, varscan2
- CRHR1 | chr17:45784496 A>G | 5'Flank (SNP) | VAF 66/66 reads (100%) | called by muse, mutect2, varscan2
- CTDSP1 | chr2:218398405 G>A | 5'Flank (SNP) | VAF 100/221 reads (45%) | catalogued as rs1315222373; called by muse, mutect2, varscan2
- CYB561 | c.405+49G>A | Intron (SNP) | VAF 132/140 reads (94%) | called by muse, mutect2, varscan2
- DAP3 | c.*90G>A | 3'UTR (SNP) | VAF 67/124 reads (54%) | called by muse, mutect2, varscan2
- DCDC1 | c.4308+25G>A | Intron (SNP) | VAF 107/214 reads (50%) | catalogued as rs772815194; called by muse, mutect2, varscan2
- DEAF1 | c.*39C>A | 3'UTR (SNP) | VAF 88/190 reads (46%) | called by muse, mutect2, varscan2
- DNAAF3 | c.481-9G>T | Intron (SNP) | VAF 182/530 reads (34%) | called by muse, mutect2
- DSC3 | c.*15A>C | 3'UTR (SNP) | VAF 13/264 reads (5%) | called by muse, mutect2
- DUOX2 | c.513+37C>T | Intron (SNP) | VAF 141/327 reads (43%) | called by muse, mutect2, varscan2
- DUSP10 | c.-38C>T | 5'UTR (SNP) | VAF 150/319 reads (47%) | called by muse, mutect2, varscan2
- ECHDC2 | c.364+26G>A | Intron (SNP) | VAF 106/188 reads (56%) | called by muse, mutect2, varscan2
- EIF2B4 | c.32-65T>C | Intron (SNP) | VAF 100/212 reads (47%) | catalogued as rs1433998363; called by muse, mutect2, varscan2
- ELMO2 | c.*2C>T | 3'UTR (SNP) | VAF 180/348 reads (52%) | called by muse, mutect2, varscan2
- ETV7 | c.307+24C>T | Intron (SNP) | VAF 267/274 reads (97%) | catalogued as rs1277263661; called by muse, mutect2, varscan2
- FAM120A | c.1734+43A>G | Intron (SNP) | VAF 125/301 reads (42%) | called by muse, mutect2, varscan2
- FBRS | chr16:30660447 G>A | 5'Flank (SNP) | VAF 190/198 reads (96%) | called by muse, mutect2, varscan2
- FDFT1 | c.100-107G>A | Intron (SNP) | VAF 470/490 reads (96%) | catalogued as rs373307057; called by muse, mutect2, varscan2
- FERMT2 | c.1869+32T>C | Intron (SNP) | VAF 65/149 reads (44%) | called by muse, mutect2, varscan2
- FEZ1 | c.667+30G>A | Intron (SNP) | VAF 82/173 reads (47%) | called by muse, mutect2, varscan2
- FKBP11 | c.388+225C>T | Intron (SNP) | VAF 160/365 reads (44%) | called by muse, mutect2, varscan2
- FOXM1 | c.1266+23A>G | Intron (SNP) | VAF 190/207 reads (92%) | called by muse, varscan2
- FOXP1 | c.181-18106A>G | Intron (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- FYN | c.862+558G>A | Intron (SNP) | VAF 196/398 reads (49%) | called by muse, mutect2, varscan2
- GDF1 | c.-234C>T | 5'UTR (SNP) | VAF 72/141 reads (51%) | called by muse, mutect2, varscan2
- GLMP | c.798+10C>T | Intron (SNP) | VAF 218/483 reads (45%) | called by muse, mutect2, varscan2
- GNLY | c.52+74C>T | Intron (SNP) | VAF 133/228 reads (58%) | called by muse, mutect2, varscan2
- GPT2 | c.821-10G>A | Intron (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- GPX3 | c.242-80G>A | Intron (SNP) | VAF 34/36 reads (94%) | called by muse, mutect2, varscan2
- GRK2 | c.504-97G>A | Intron (SNP) | VAF 20/47 reads (43%) | catalogued as rs1305274758; called by muse, mutect2, varscan2
- GSK3B | c.1096+80A>G | Intron (SNP) | VAF 53/114 reads (46%) | called by muse, mutect2, varscan2
- HIP1R | c.-86C>T | 5'UTR (SNP) | VAF 16/32 reads (50%) | catalogued as rs929183631; called by muse, mutect2, varscan2
- HMCES | c.*98G>A | 3'UTR (SNP) | VAF 37/64 reads (58%) | called by muse, mutect2, varscan2
- HSPBP1 | c.-94-53T>C | Intron (SNP) | VAF 204/589 reads (35%) | called by muse, mutect2, varscan2
- IFI16 | c.-247C>G | 5'UTR (SNP) | VAF 138/321 reads (43%) | called by muse, mutect2, varscan2
- IKBKB | c.1987-26T>C | Intron (SNP) | VAF 32/33 reads (97%) | called by muse, mutect2, varscan2
- ILF2 | c.-38G>A | 5'UTR (SNP) | VAF 179/400 reads (45%) | called by muse, mutect2, varscan2
- INTS6 | c.112-83G>A | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- LIG1 | c.2440-30T>C | Intron (SNP) | VAF 275/461 reads (60%) | catalogued as rs1449233922; called by muse, mutect2, varscan2
- LINC02874 | n.396C>T | RNA (SNP) | VAF 105/256 reads (41%) | called by muse, mutect2, varscan2
- LRRC2 | c.-20+482G>A | Intron (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2
- LSM12 | c.*40G>A | 3'UTR (SNP) | VAF 100/129 reads (78%) | called by muse, mutect2, varscan2
- MAB21L1 | c.-28G>A | 5'UTR (SNP) | VAF 41/85 reads (48%) | catalogued as COSV100075558, COSV59760929; called by muse, mutect2, varscan2
- MIS18A | c.*40C>T | 3'UTR (SNP) | VAF 40/131 reads (31%) | catalogued as rs1340018236; called by muse, mutect2, varscan2
- MPP3 | c.-37-104C>T | Intron (SNP) | VAF 37/37 reads (100%) | called by muse, mutect2, varscan2
- MTA3 | c.1759+20C>T | Intron (SNP) | VAF 125/269 reads (46%) | called by muse, mutect2, varscan2
- MXRA8 | c.-27G>A | 5'UTR (SNP) | VAF 123/334 reads (37%) | catalogued as rs1412887749, COSV100491761; called by muse, mutect2, varscan2
- MYZAP | c.-61C>A | 5'UTR (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- NAB1 | c.*36C>A | 3'UTR (SNP) | VAF 150/356 reads (42%) | called by muse, mutect2, varscan2
- NAPRT | c.355-33G>A | Intron (SNP) | VAF 91/249 reads (37%) | called by muse, mutect2, varscan2
- NFATC3 | c.3107-94G>A | Intron (SNP) | VAF 94/99 reads (95%) | called by muse, mutect2, varscan2
- NOL12 | c.*37G>A | 3'UTR (SNP) | VAF 136/139 reads (98%) | catalogued as rs1479058307; called by muse, mutect2, varscan2
- NOTCH2 | c.5003-77C>T | Intron (SNP) | VAF 93/213 reads (44%) | catalogued as rs959466891; called by muse, mutect2, varscan2
- NOTCH4 | c.3232-91C>T | Intron (SNP) | VAF 27/29 reads (93%) | catalogued as rs1197237781; called by muse, mutect2, varscan2
- NR2C2AP | c.-63G>A | 5'UTR (SNP) | VAF 55/109 reads (50%) | called by muse, mutect2, varscan2
- OPRM1 | c.1164+1813T>C | Intron (SNP) | VAF 140/250 reads (56%) | called by muse, mutect2, varscan2
- P4HTM | c.1073+124G>A | Intron (SNP) | VAF 217/416 reads (52%) | catalogued as rs567293554; called by muse, mutect2, varscan2
- PCYOX1L | c.-6C>T | 5'UTR (SNP) | VAF 347/358 reads (97%) | catalogued as rs773612605; called by muse, mutect2, varscan2
- PGPEP1 | c.*1G>A | 3'UTR (SNP) | VAF 121/327 reads (37%) | called by muse, mutect2, varscan2
- PITRM1 | c.3020+34C>T | Intron (SNP) | VAF 16/91 reads (18%) | called by muse, mutect2, varscan2
- PLCG2 | c.2582-24del | Intron (DEL) | VAF 247/341 reads (72%) | called by mutect2, pindel, varscan2
- POMGNT1 | c.-646A>G | 5'UTR (SNP) | VAF 52/116 reads (45%) | called by muse, mutect2, varscan2
- PPIL2 | c.1466+96G>A | Intron (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- PRR15 | c.-29G>T | 5'UTR (SNP) | VAF 84/195 reads (43%) | called by muse, mutect2, varscan2
- PRSS47 | n.51C>A | RNA (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2
- PSMD6 | c.145+35G>A | Intron (SNP) | VAF 176/356 reads (49%) | called by muse, mutect2, varscan2
- PSME1 | c.*8C>T | 3'UTR (SNP) | VAF 96/216 reads (44%) | catalogued as rs921423100; called by muse, mutect2, varscan2
- PTCH1 | c.*1+54G>A | Intron (SNP) | VAF 146/289 reads (51%) | called by muse, mutect2, varscan2
- PTOV1 | c.714+36G>A | Intron (SNP) | VAF 138/364 reads (38%) | catalogued as rs758090975; called by muse, mutect2, varscan2
- RADIL | c.2291-65G>A | Intron (SNP) | VAF 48/92 reads (52%) | catalogued as rs1237646787; called by muse, mutect2, varscan2
- RFX4 | c.994-48G>A | Intron (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- SARAF | c.103+69C>T | Intron (SNP) | VAF 40/40 reads (100%) | called by muse, mutect2, varscan2
- SARM1 | c.-16C>T | 5'UTR (SNP) | VAF 53/60 reads (88%) | called by muse, mutect2, varscan2
- SHISA8 | chr22:41911243 G>A | 3'Flank (SNP) | VAF 226/236 reads (96%) | called by muse, mutect2, varscan2
- SLC22A2 | c.1064+90C>T | Intron (SNP) | VAF 71/137 reads (52%) | called by muse, mutect2, varscan2
- SLC52A1 | c.-36C>T | 5'UTR (SNP) | VAF 188/191 reads (98%) | catalogued as rs997697467; called by muse, mutect2, varscan2
- SLC6A9 | c.-8A>G | 5'UTR (SNP) | VAF 129/318 reads (41%) | called by muse, mutect2, varscan2
- SLC8B1 | c.*21G>A | 3'UTR (SNP) | VAF 128/312 reads (41%) | catalogued as rs1462914850; called by muse, mutect2, varscan2
- SLC8B1 | c.1412-48G>T | Intron (SNP) | VAF 41/60 reads (68%) | called by muse, mutect2, varscan2
- SP100 | c.-41A>G | 5'UTR (SNP) | VAF 82/160 reads (51%) | called by muse, mutect2, varscan2
- SPDYE18 | n.643C>T | RNA (SNP) | VAF 52/117 reads (44%) | called by mutect2, varscan2
- SULF2 | c.2528+81C>T | Intron (SNP) | VAF 69/128 reads (54%) | catalogued as rs1009828023; called by muse, mutect2, varscan2
- SUMF2 | c.734-37G>A | Intron (SNP) | VAF 148/345 reads (43%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-5C>T | 5'UTR (SNP) | VAF 105/264 reads (40%) | called by muse, mutect2, varscan2
- THBS3 | chr1:155207929 G>A | 5'Flank (SNP) | VAF 34/75 reads (45%) | catalogued as rs993266795; called by muse, mutect2, varscan2
- THUMPD3 | c.939-77T>C | Intron (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- TM9SF2 | c.-94T>C | 5'UTR (SNP) | VAF 38/80 reads (48%) | called by muse, mutect2, varscan2
- TMEM71 | c.677-52T>C | Intron (SNP) | VAF 69/188 reads (37%) | called by muse, mutect2, varscan2
- TMPO | c.280-92T>C | Intron (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- TMX2 | c.251-63G>A | Intron (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- TNC | c.*25A>G | 3'UTR (SNP) | VAF 145/295 reads (49%) | catalogued as rs373608048; called by muse, mutect2, varscan2
- TRIM7 | c.989-53C>T | Intron (SNP) | VAF 46/46 reads (100%) | catalogued as rs1219039108; called by muse, mutect2, varscan2
- TRPM1 | c.213+94C>A | Intron (SNP) | VAF 199/401 reads (50%) | called by muse, mutect2, varscan2
- UBAP2 | c.*36T>C | 3'UTR (SNP) | VAF 141/145 reads (97%) | called by muse, mutect2, varscan2
- UBIAD1 | c.*45T>C | 3'UTR (SNP) | VAF 88/223 reads (39%) | called by muse, mutect2, varscan2
- UCHL1 | c.585+78T>C | Intron (SNP) | VAF 65/151 reads (43%) | called by muse, mutect2, varscan2
- UPF3A | c.631+177T>C | Intron (SNP) | VAF 126/307 reads (41%) | called by muse, mutect2, varscan2
- VILL | c.2205+44C>T | Intron (SNP) | VAF 107/228 reads (47%) | catalogued as rs1559368444; called by muse, mutect2, varscan2
- ZBED8 | c.*94T>C | 3'UTR (SNP) | VAF 38/40 reads (95%) | called by muse, mutect2, varscan2
- ZC2HC1C | c.*59C>T | 3'UTR (SNP) | VAF 98/201 reads (49%) | called by muse, mutect2, varscan2
- ZNF598 | c.2054-65C>T | Intron (SNP) | VAF 51/53 reads (96%) | called by muse, mutect2, varscan2
